Gene-level copy-number profile of tumor specimen TCGA-AR-A2LK-01A from TCGA case TCGA-AR-A2LK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 62.4 years (22,800 days).
Specimen TCGA-AR-A2LK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.263be494-445c-469b-8b53-d27860d73f8d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A2LK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ad8ebc30-950d-4ff9-821a-cc78701b8269

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 27,214; copy number 3: 17,631; copy number 4: 6,150; copy number 5: 6,763; copy number 6: 224; copy number 7: 1,562; copy number 8: 92; copy number 10: 19; copy number 11: 95; copy number 13: 28; copy number 16: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A2LK-01A-11D-A17U-01): tumor purity 0.76, ploidy 3.03, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,823 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,602 genes, copy number 5–7 (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,985 genes, copy number 5 (broad region; genes not listed).
- chr8:41,032,892–145,066,685, 1,615 genes, copy number 6–13 (broad region; genes not listed).
- chr11:56,288,462–56,736,462, 37 genes, copy number 6: OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P, OR5AL1, OR5R1, OR5M4P, AP002512.3, OR5M9, OR5M3, OR5M2P, OR5M8, AP002512.1, OR5M7P, AP002512.2, OR5M6P, OR5M5P, OR5M11, OR5M10, OR5M13P, OR5M1, OR5AM1P, OR5M12P, OR5AP1P, OR5AP2, OR5AR1, OR2AH1P, TMEM230P2, OR9G1, AP001803.1.
- chr11:65,314,866–71,568,934, 277 genes, copy number 6–16 (broad region; genes not listed).
- chr11:71,579,728–71,579,848, 1 gene, copy number 10: KRTAP5-14P.
- chr16:11,555–33,771,248, 1,306 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
